Gene-level copy-number profile of tumor specimen TCGA-69-8453-01A from TCGA case TCGA-69-8453, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.8 years (28,413 days).
Specimen TCGA-69-8453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b53f998b-216f-4be5-8752-90e3c14ef639.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-8453-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/acf07138-fa3a-456d-8f97-ea03dc1dfd7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 12,106; copy number 2: 46,745; copy number 3: 814; copy number 4: 22; copy number 5: 98; copy number 9: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-69-8453-01): tumor purity 0.56, ploidy 3.76, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 124 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:20,946,906–27,190,698, 123 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).
- chr18:26,952,201–26,952,558, 1 gene, copy number 9: ATP6V1E1P2.

Autosomal genes at a single copy (total copy number 1): 9,739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
